TCGA case TCGA-Q1-A73Q — Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma (TCGA-CESC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Cervix uteri; Tissue source site: University of Oklahoma HSC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/5c72bda2-2ec0-455f-ab27-7247fd5ffff9

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 46 years; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, keratinizing, NOS: ICD-O-3 morphology code: 8071/3; ICD-10 code: C53.9; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 46.1 years (16,851 days); Year of diagnosis: 2013; Method of diagnosis: Biopsy; AJCC pathologic T: TX; AJCC pathologic N: NX; AJCC pathologic M: MX; FIGO stage: Stage I; FIGO staging edition year: 2009; Tumor grade: GX; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Days to treatment start: 24 days; Days to treatment end: 45 days; Clinical trial indicator: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 26 days; Days to treatment end: 173 days; Treatment dose: 4,500 cGy; Number of fractions: 25; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Brachytherapy, High Dose; Treatment intent type: Adjuvant; Treatment dose: 2,900 cGy; Chemo concurrent to radiation: Yes; Timepoint category: Postoperative.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Cisplatin; Treatment intent type: Adjuvant; Number of cycles: 5; Chemo concurrent to radiation: Yes; Prescribed dose: 40; Prescribed dose units: mg/m2; Timepoint category: Postoperative; Treatment frequency: Once Weekly.

Follow-up (2 entries)
- Day 179 (post adjuvant therapy): ECOG performance status: 0.
- Days to follow up: 284 days; Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Menopause status: Premenopausal; Pregnant at diagnosis: No.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 1; Pregnancy outcome: Ectopic Pregnancy.
- Timepoint category: Initial Diagnosis; Weight: 87 kg; Height: 158 cm; BMI: 34.9.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 1; Pregnancy outcome: Live Birth.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 3.3; Age at onset: 13.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-Q1-A73Q-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 1,260 mg.
  Slide TCGA-Q1-A73Q-01A-02-TSB: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 20; Percent lymphocyte infiltration: 40; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 20.
- Sample TCGA-Q1-A73Q-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-Q1-A73Q-10B: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; Menopause status: Pre (<6 months since LMP AND no prior bilateral ovariectomy AND not on estrogen replacement); History neoadjuvant treatment: No; Live birth pregnancy count: 1; Pregnancies count ectopic: 1; Total pregnancy count: 2; Tobacco smoking history indicator: 2; Performance status timing: Post-Adjuvant Therapy; Submitted tumor site: Cervical; Histologic diagnosis: Cervical Squamous Cell Carcinoma; Keratinization squamous cell: Keratinizing squamous cell carcinoma; Method initial path diagnosis: Biopsy (cervical / CT-guided / Other); Lymph nodes examined: No; New tumor event diagnosis indicator: No.
- Treatment, Radiation therapy info: Brachytherapy type: HDR.
- Treatment, Concurrent prescription treatment info, Concurrent prescription treatment: Chemo concurrent dose: 40mg/m2; Chemo concurrent fractions total: 5.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; Treatment outcome at TCGA followup: Partial Response; New tumor event diagnosis indicator: No.
- Follow-up form, Treatment, Radiation therapy info: Brachytherapy type: HDR; Brachytherapy total dose point a: 1740; Radiation therapy xrt type: 3D conformal.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 284 days; disease-specific survival: no event (censored), 284 days; progression-free interval: no event (censored), 284 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-Q1-A73Q-01A-21D-A32H-01): tumor purity 0.84, ploidy 2.02, whole-genome doublings 0.
